Gene-level copy-number profile of tumor specimen TCGA-33-A5GW-01A from TCGA case TCGA-33-A5GW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.3 years (24,586 days).
Specimen TCGA-33-A5GW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b0f82932-4369-4c0d-870d-e6c0f7c14beb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-A5GW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/610f5718-484c-490c-8bee-74b37b2bc0c4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 16,810; copy number 3: 2,971; copy number 4: 37,917; copy number 5: 392; copy number 6: 621; copy number 7: 997; copy number 9: 23; copy number 10: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-A5GW-01A-11D-A27J-01): tumor purity 0.82, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 103 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:70,013,982–71,489,976, 23 genes, copy number 9 (within-gene range 4–9): LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5, CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186, ZRANB2-AS2, AL358453.1.
- chr12:68,487,687–72,670,758, 80 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
